Somatic mutation profile of tumor specimen TCGA-AP-A1DO-01A (aliquot TCGA-AP-A1DO-01A-11D-A135-09) from TCGA case TCGA-AP-A1DO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 62.4 years (22,787 days).
Specimen TCGA-AP-A1DO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e58e08a-a3e3-448d-96c5-1ce6ba4a7c8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DO-10A (Blood Derived Normal), aliquot TCGA-AP-A1DO-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10fe352d-665f-43db-ba32-1bc7d42d6d7f

The open-access MAF lists 678 somatic variants for this specimen: 513 protein-altering or splice-affecting, 143 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 322, Silent 143, Frame Shift Del 126, Frame Shift Ins 33, Nonsense Mutation 14, Intron 10, In Frame Del 8, Splice Site 5, 5'Flank 4, Splice Region 4, RNA 3, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CYP27B1 | c.171dup p.L58Afs*275 | Frame Shift Ins (INS) | VAF 29/57 reads (51%) | catalogued as rs763437121; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 28/40 reads (70%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 39/46 reads (85%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | catalogued as rs781585299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PDZD7 | c.166dup p.R56Pfs*24 | Frame Shift Ins (INS) | VAF 50/126 reads (40%) | catalogued as rs587776894; ClinVar: pathogenic / risk factor; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.389del p.R130Qfs*4 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs121913292, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic; called by pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 50/88 reads (57%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- ABHD15 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145964335; called by muse, mutect2, varscan2
- AC008676.3 | c.635del p.G212Vfs*24 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs748255153; called by mutect2, pindel
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAM7 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759801023, COSV99443977; called by muse, mutect2, varscan2
- ADAMTS10 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.036); catalogued as rs143780237; called by muse, mutect2, varscan2
- ADCY4 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99353230; called by muse, mutect2, varscan2
- ADGRL1 | c.781C>T p.R261C (on ENST00000340736 / NM_001008701.3; = p.R256C on NM_014921.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756833889, COSV100529538; called by muse, mutect2, varscan2
- ADGRL4 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as COSV100875967, COSV66058997; called by muse, mutect2, varscan2
- ADM | c.530dup p.S178Efs*19 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs773405081; called by mutect2, varscan2
- AFAP1L2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs754748689, COSV58414737; called by muse, mutect2, varscan2
- AFP | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV99890003; called by muse, mutect2, varscan2
- AGAP4 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs879967164; called by muse, mutect2, varscan2
- AHNAK2 | c.6556G>A p.D2186N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs760653505, COSV100317557; called by muse, mutect2
- AHNAK2 | c.6061G>A p.D2021N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs370710538; called by muse, mutect2, varscan2
- AIRE | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV99381160; called by muse, mutect2, varscan2
- AKAP10 | c.656A>G p.H219R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99855454; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AMPD3 | c.1046G>A p.R349Q (on ENST00000396553 / NM_001025389.2; = p.R358Q on NM_000480.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs201733675, COSV101158172; called by mutect2, varscan2
- ANKRD11 | c.5519C>T p.A1840V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs139088883; called by mutect2, varscan2
- ANKRD24 | c.1141_1143del p.K381del | In Frame Del (DEL) | VAF 14/22 reads (64%) | catalogued as rs1398060093; called by mutect2, pindel, varscan2
- ANKRD34A | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100041260; called by muse, varscan2
- ANKRD50 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs758994260, COSV72386364; called by muse, mutect2, varscan2
- APCDD1L | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs201769185, COSV100953987; called by muse, mutect2, varscan2
- APCDD1L | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as COSV100953992; called by muse, mutect2, varscan2
- APH1A | c.625T>A p.W209R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99354398; called by muse, mutect2, varscan2
- ARHGAP24 | c.1715G>A p.R572H (on ENST00000395184 / NM_001025616.3; = p.R479H on NM_031305.3) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs149024248; called by muse, mutect2, varscan2
- ARHGEF28 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765756455, COSV99709100; called by muse, mutect2, varscan2
- ARL4A | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100775922; called by muse, mutect2, varscan2
- ASAP2 | c.1307G>A p.C436Y | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856219; called by muse, mutect2, varscan2
- ASCC2 | c.191A>T p.N64I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV100316274; called by muse, mutect2, varscan2
- ASTN1 | c.3344A>T p.E1115V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100706787; called by muse, mutect2
- ATCAY | c.1072A>G p.R358G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100008741; called by muse, mutect2, varscan2
- ATF7IP2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100202628; called by muse, mutect2, varscan2
- ATL3 | c.1367T>C p.I456T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100219861; called by mutect2, varscan2
- ATP4A | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99382601; called by muse, mutect2, varscan2
- ATXN1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV99786489; called by muse, mutect2, varscan2
- AVPR1B | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.739); catalogued as rs782615581, COSV100899375; called by muse, mutect2, varscan2
- BAZ1B | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100289797; called by muse, mutect2, varscan2
- BMP2 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs370948498, COSV66577849; called by muse, mutect2
- BMT2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99774633; called by muse, mutect2, varscan2
- BRINP1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99775504; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs746043904; called by mutect2, varscan2
- C12orf71 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as rs201692205; called by muse, mutect2, varscan2
- C1orf198 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs370439547; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, varscan2
- CACNA1E | c.5894C>A p.S1965Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.397); catalogued as COSV62406616; called by muse, mutect2, varscan2
- CACNA1E | c.6870del p.P2291Lfs*5 (on ENST00000367573 / NM_001205293.3; = p.P2248Lfs*5 on NM_000721.4) | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as COSV62409794; called by mutect2, pindel
- CALCOCO1 | c.1331G>T p.R444M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100017340; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN3 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs190793093, CM148887, CM990320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASQ1 | c.1127G>A p.W376* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100850146; called by muse, mutect2, varscan2
- CBX2 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV99490876; called by muse, mutect2, varscan2
- CCAR2 | c.1249dup p.R417Pfs*49 | Frame Shift Ins (INS) | VAF 41/72 reads (57%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs747131147; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 26/45 reads (58%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 15/74 reads (20%) | catalogued as rs768846308; called by mutect2, pindel, varscan2
- CCDC96 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV100027937; called by muse, mutect2, varscan2
- CCDC9B | c.294dup p.M99Dfs*12 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | catalogued as rs765438623; called by mutect2, varscan2
- CD70 | c.365G>T p.R122M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV99835571; called by muse, mutect2, varscan2
- CDH23 | c.10006C>T p.P3336S | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1449615366, COSV99821068; called by muse, mutect2, varscan2
- CDH26 | c.2128A>C p.S710R (on ENST00000348616 / NM_177980.4; = p.S43R on NM_021810.6) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99722448; called by muse, mutect2
- CEP112 | c.2394G>T p.K798N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67136295; called by muse, mutect2, varscan2
- CHCHD6 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs560723536, COSV99336238; called by muse, mutect2, varscan2
- CHRNA1 | c.760C>T p.R254C (on ENST00000261007 / NM_001039523.3; = p.R229C on NM_000079.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745355427, CM132621, COSV53681813; called by mutect2, varscan2
- CHSY3 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs746758769, COSV100519121; called by muse, mutect2, varscan2
- CLCN3 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV100641720, COSV61628243; called by muse, mutect2, varscan2
- CLDN18 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100648255; called by muse, mutect2, varscan2
- CLSPN | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1389154685, COSV52052778; called by muse, mutect2, varscan2
- CNKSR3 | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.988); catalogued as COSV101401364, COSV70481609; called by muse, mutect2, varscan2
- CNNM1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63201736; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- COIL | c.485dup p.N162Kfs*6 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as COSV100615079, COSV62186140; called by mutect2, varscan2
- COL27A1 | c.5108-2A>G p.X1703_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100621018; called by muse, mutect2, varscan2
- COL6A3 | c.4270C>T p.R1424C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs768522226, COSV99798394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.2674C>A p.P892T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100294825; called by muse, mutect2, varscan2
- COQ8A | c.1805del p.P602Hfs*22 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as rs768233728; called by mutect2, pindel, varscan2
- CPS1 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114311, COSV51811220, COSV99243070; called by muse, mutect2, varscan2
- CR1L | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV99687410; called by muse, mutect2, varscan2
- CSF2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.759); catalogued as rs1161863330, COSV51522338; called by muse, mutect2, varscan2
- CSNK2A1 | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99424416; called by muse, mutect2, varscan2
- CT55 | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV99358882; called by muse, mutect2, varscan2
- CYP17A1 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs1290838496, COSV100882110; called by muse, mutect2, varscan2
- CYP2D6 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100637311; called by muse, mutect2, varscan2
- CYP4F3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs377074942; called by muse, varscan2
- DCAF11 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100386709; called by muse, mutect2, varscan2
- DCAF4L1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60787502; called by muse, mutect2, varscan2
- DCAF8 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1173427133, COSV100470483; called by muse, mutect2, varscan2
- DCC | c.1721A>G p.Q574R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); catalogued as COSV100500173; called by muse, mutect2, varscan2
- DDX21 | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs780127993, COSV100826519; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 20/31 reads (65%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX50 | c.321dup p.S108Ifs*13 | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | catalogued as rs765365418; called by mutect2, varscan2
- DDX53 | c.787A>C p.I263L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100028936; called by muse, mutect2, varscan2
- DEFB4A | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs538256130, COSV100156638; called by muse, mutect2, varscan2
- DENND4B | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100768690; called by muse, mutect2, varscan2
- DHX35 | c.550T>A p.Y184N | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52668797, COSV99326863; called by muse, mutect2, varscan2
- DISP2 | c.3683G>A p.C1228Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs560958430, COSV99140015; called by muse, mutect2, varscan2
- DLGAP2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.997); catalogued as COSV101421924; called by muse, mutect2, varscan2
- DMD | c.8332C>T p.R2778C | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368974772, COSV100627286; called by muse, mutect2, varscan2
- DMXL2 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs759813761, COSV99196387; called by mutect2, varscan2
- DNAH5 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99449950; called by muse, mutect2, varscan2
- DNAH9 | c.12691C>T p.R4231W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs373580958; called by muse, mutect2, varscan2
- DNAJC10 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV99899281; called by muse, mutect2, varscan2
- DNAJC13 | c.4115T>A p.I1372N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99607301; called by muse, mutect2, varscan2
- DSCAM | c.3851-2A>G p.X1284_splice | Splice Site (SNP) | VAF 11/26 reads (42%) | catalogued as COSV101260206; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1064C>T p.S355L (on ENST00000361735 / NM_015935.5; = p.S269L on NM_014955.3) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs200343786, COSV62283385; called by muse, mutect2, varscan2
- EIF4G1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100071815; called by muse, mutect2, varscan2
- ELK3 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1482212439, COSV99957636; called by muse, mutect2, varscan2
- ENPP4 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320320; called by muse, mutect2, varscan2
- EP400 | c.6989C>A p.P2330H | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201261; called by muse, mutect2, varscan2
- EPHA5 | c.460T>C p.Y154H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99898980; called by muse, mutect2, varscan2
- EPOR | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs772993810, COSV55799672; called by muse, mutect2, varscan2
- ESD | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.909); catalogued as COSV101099152; called by muse, mutect2
- EVA1A | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs547549349, COSV99285600; called by muse, mutect2, varscan2
- EXPH5 | c.5081G>A p.S1694N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV99761666; called by muse, mutect2, varscan2
- EYA4 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62045399, COSV62052612; called by muse, mutect2, varscan2
- F13A1 | c.1439A>T p.D480V | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV99343052; called by muse, mutect2, varscan2
- FAM111B | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.172); catalogued as COSV100639290; called by muse, mutect2, varscan2
- FBN2 | c.3451A>G p.M1151V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs1042256829, COSV99327547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO31 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs534059001, COSV100291421; called by muse, mutect2, varscan2
- FER1L5 | c.4756G>A p.D1586N (on ENST00000623019; = p.D1559N on NM_001293083.2) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750545075, COSV67606103; called by muse, mutect2, varscan2
- FERMT3 | c.1115G>A p.G372D (on ENST00000279227 / NM_178443.3; = p.G368D on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs897637418, COSV99656597; called by muse, mutect2, varscan2
- FGD1 | c.2771C>T p.T924M | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1247164376, COSV64308627; called by muse, mutect2, varscan2
- FMNL2 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs764381846, COSV99979721; called by muse, mutect2, varscan2
- FNDC1 | c.2399A>G p.Q800R | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV99795861; called by muse, mutect2, varscan2
- FNDC8 | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.998); catalogued as COSV99338776, COSV99338792; called by muse, mutect2, varscan2
- FREM2 | c.6173G>T p.G2058V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99748832; called by muse, mutect2, varscan2
- FRMD5 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs1243138958, COSV101296528; called by muse, mutect2, varscan2
- FSIP1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs542523952, COSV99052129; called by muse, mutect2, varscan2
- GALNS | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs377591464; called by muse, mutect2, varscan2
- GDI2 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs751756095, COSV100049878, COSV100050514; called by muse, mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs746795576; called by mutect2, varscan2
- GIT2 | c.1174T>A p.Y392N (on ENST00000355312 / NM_057169.5; = p.Y394N on NM_014776.5) | Missense Mutation (SNP) | VAF 99/102 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100189049; called by muse, mutect2, varscan2
- GJD2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV99290750; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GPC5 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV100994058; called by muse, mutect2, varscan2
- GPRIN2 | c.1289T>A p.V430E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100966391; called by muse, mutect2, varscan2
- GRAMD2B | c.381A>C p.Q127H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99587077; called by muse, mutect2, varscan2
- GRIN2A | c.1968G>T p.E656D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100409832, COSV58044827; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 35/92 reads (38%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF3C2 | c.515del p.P172Lfs*47 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV104391949; called by mutect2, pindel, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 76/111 reads (68%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- GUSB | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100512629; called by muse, mutect2, varscan2
- H1-4 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs761734336, COSV56802747, COSV56802752; called by muse, mutect2, varscan2
- H3C13 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV100516118; called by muse, mutect2, varscan2
- HACE1 | c.1829A>T p.N610I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99493687; called by muse, mutect2, varscan2
- HAX1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1558251527, COSV99671324; called by muse, mutect2
- HDAC8 | c.710A>T p.D237V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101003302; called by muse, mutect2, varscan2
- HELB | c.2969C>T p.T990I | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs777112164, COSV99921922; called by muse, mutect2, varscan2
- HHATL | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); catalogued as rs527729294, COSV60041217; called by mutect2, varscan2
- HIPK2 | c.1625A>T p.K542I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100702258; called by muse, mutect2, varscan2
- HNRNPDL | c.285A>G p.I95M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs763589139, COSV99787099; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs777829525; called by mutect2, varscan2
- HPS6 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100154881; called by muse, mutect2, varscan2
- HRNR | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs551365531, COSV64254273; called by muse, mutect2, varscan2
- HSD17B8 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100761783; called by muse, mutect2, varscan2
- HTR1A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as COSV60500871; called by muse, mutect2, varscan2
- HTT | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs899196481, COSV61866367; called by muse, mutect2, varscan2
- IGDCC4 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1281720284, COSV61539995; called by muse, mutect2, varscan2
- IGF1R | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs1356080771, COSV51276334; called by muse, mutect2, varscan2
- IGSF1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763136637, COSV63840416; called by mutect2, varscan2
- IL3 | c.48del p.G17Dfs*6 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs762242459, COSV57308459; called by mutect2, pindel, varscan2
- IL36A | c.77A>C p.Q26P | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99382120; called by muse, mutect2, varscan2
- INIP | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as rs376380195, COSV100954112; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 15/24 reads (63%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSRR | c.940A>G p.S314G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100947532; called by muse, mutect2
- INTS1 | c.6158G>A p.R2053Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1007524829, COSV101247932; called by muse, mutect2, varscan2
- IRX1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57359216; called by muse, mutect2, varscan2
- ITPKC | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs899609945, COSV99648753; called by muse, mutect2, varscan2
- IWS1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs368651104; called by muse, mutect2, varscan2
- JAG1 | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652894; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | catalogued as rs755650243; called by mutect2, varscan2
- JMJD7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs775673685, COSV100583932; called by muse, varscan2
- KBTBD2 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100406500; called by muse, mutect2, varscan2
- KCNA5 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs773432359, COSV52905456; called by muse, mutect2, varscan2
- KCNH8 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 51/58 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376188228; called by muse, mutect2, varscan2
- KCNN2 | c.1075A>G p.I359V (on ENST00000264773; = p.I571V on NM_021614.4) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.557); catalogued as rs765149039, COSV99299795; called by muse, mutect2, varscan2
- KIAA0100 | c.2783C>T p.A928V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1424876534, COSV66491145; called by muse, mutect2, varscan2
- KIAA0930 | c.740G>A p.G247D (on ENST00000336156 / NM_001009880.2; = p.G252D on NM_015264.2) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99325817; called by muse, mutect2, varscan2
- KLHL6 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.241); catalogued as COSV100384667; called by muse, mutect2, varscan2
- KMT2B | c.7886A>G p.Y2629C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99495148; called by muse, mutect2, varscan2
- KPNB1 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393584201, COSV51596909; called by muse, mutect2, varscan2
- LAMB1 | c.4261G>T p.G1421* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99740761; called by muse, mutect2, varscan2
- LAMB3 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.027); catalogued as rs745366407; called by muse, mutect2, varscan2
- LCLAT1 | c.171del p.F57Lfs*7 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1558496792; called by mutect2, pindel, varscan2
- LEMD1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV100903459; called by muse, mutect2, varscan2
- LINGO2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs779519807, COSV100430570; called by muse, mutect2, varscan2
- LMAN1L | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100547710; called by muse, mutect2, varscan2
- LMAN2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs759011158, COSV57424202, COSV57424360; called by muse, mutect2, varscan2
- LMO7 | c.143G>T p.R48M (on ENST00000357063; = p.R63M on NM_005358.5) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV100442739; called by muse, mutect2, varscan2
- LPAR2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.924); catalogued as rs951958714, COSV99179288; called by muse, mutect2, varscan2
- LRG1 | c.398del p.P133Rfs*15 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as COSV56703831; called by mutect2, pindel, varscan2
- LRIG2 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs371835362; called by muse, mutect2, varscan2
- LRP1B | c.10459_10461del p.N3487del | In Frame Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs766287163; called by pindel, varscan2
- LRRC52 | c.91_94del p.L31Vfs*6 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs760411659; called by mutect2, pindel, varscan2
- LRRC56 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99530123; called by muse, mutect2, varscan2
- LRSAM1 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as rs555377969, COSV100031510; called by muse, mutect2, varscan2
- LTBP4 | c.4224dup p.A1409Rfs*3 (on ENST00000308370 / NM_001042544.1; = p.A1372Rfs*3 on NM_003573.2) | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs754757253; called by mutect2, varscan2
- LY9 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs374075565; called by muse, mutect2, varscan2
- MACROH2A2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs375442516; called by muse, mutect2, varscan2
- MAEA | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV53264429; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs758700583; called by mutect2, varscan2
- MANEA | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100721538; called by muse, mutect2, varscan2
- MAP1A | c.7073C>T p.A2358V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV100288679; called by muse, mutect2, varscan2
- MAPK14 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100004926; called by muse, mutect2, varscan2
- MAST3 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs775545026, COSV99445355; called by muse, mutect2, varscan2
- MAVS | c.170A>T p.H57L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV100816310, COSV63926474; called by muse, mutect2, varscan2
- MCOLN3 | c.137del p.F46Sfs*2 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs772812591; called by mutect2, varscan2
- MED12L | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99853210; called by muse, mutect2, varscan2
- MEIS1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV99715234; called by muse, mutect2, varscan2
- MGA | c.4591C>T p.R1531* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99580027; called by muse, mutect2, varscan2
- MGA | c.7702G>T p.G2568W (on ENST00000219905 / NM_001164273.1; = p.G2359W on NM_001080541.2) | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV54961015, COSV99580030; called by muse, mutect2, varscan2
- MLX | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs759146238, COSV53816087; called by muse, mutect2, varscan2
- MMP15 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1463139556, COSV99539481; called by muse, mutect2, varscan2
- MPHOSPH10 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV99731128; called by muse, mutect2, varscan2
- MRPL19 | c.230G>C p.S77T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); catalogued as COSV100718791; called by muse, mutect2, varscan2
- MRPS27 | c.973T>A p.S325T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.828); catalogued as COSV99782222; called by muse, mutect2, varscan2
- MTERF4 | c.448del p.Q150Sfs*3 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1559340722; called by mutect2, pindel, varscan2
- MTOR | c.4870C>T p.Q1624* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV63869690; called by muse, mutect2, varscan2
- MUC16 | c.36961G>A p.E12321K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101199986; called by muse, mutect2, varscan2
- MYH7B | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV99482801; called by muse, mutect2, varscan2
- MYO7A | c.5126C>T p.A1709V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101289134; called by muse, mutect2, varscan2
- NAV3 | c.4724G>A p.R1575Q | Missense Mutation (SNP) | VAF 107/126 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200507786, COSV57073690, COSV99891167; called by muse, mutect2, varscan2
- NAXE | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV58041164; called by muse, mutect2, varscan2
- NBL1 | c.535del p.A179Lfs*31 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as COSV57030850; called by mutect2, pindel, varscan2
- NCAPD3 | c.1529T>C p.F510S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101599367; called by muse, mutect2, varscan2
- NCOA7 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs143153057, COSV99997139; called by muse, mutect2, varscan2
- NDC80 | c.1599G>C p.E533D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55248928, COSV99859658; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOC2L | c.1631C>A p.P544Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV100498022; called by muse, varscan2
- NPBWR2 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.605); catalogued as rs376882527; called by muse, mutect2, varscan2
- NPHP4 | c.3034C>A p.P1012T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100976912; called by muse, mutect2, varscan2
- NPM3 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100761845; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs776154715; called by mutect2, varscan2
- NUGGC | c.2180G>A p.G727D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs1563212554, COSV100429267; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUTM2G | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV100672859; called by muse, mutect2, varscan2
- NWD1 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs369799191; called by muse, mutect2, varscan2
- OGFOD1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV100273035; called by muse, mutect2, varscan2
- OR6B2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs371236434; called by muse, mutect2, varscan2
- OR8B8 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs185124275; called by mutect2, varscan2
- OR8K5 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57892048; called by muse, mutect2, varscan2
- PALM | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs747841598, COSV99214535; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PC | c.136+1G>A p.X46_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100852232; called by muse, mutect2, varscan2
- PCDH10 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV52100555; called by muse, mutect2, varscan2
- PCDH8 | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.342); catalogued as COSV58811758; called by muse, mutect2, varscan2
- PCDHA11 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 88/143 reads (62%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as rs1554164932, COSV56530230; called by muse, mutect2, varscan2
- PCDHA2 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100973875; called by muse, mutect2, varscan2
- PCDHA6 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.259); catalogued as COSV67034078, COSV67044410; called by muse, mutect2, varscan2
- PCDHB11 | c.1877C>T p.T626I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV100697006; called by muse, mutect2, varscan2
- PCDHGA4 | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.944); catalogued as COSV99538630; called by muse, varscan2
- PCDHGB2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as rs535439542, COSV53898506; called by muse, mutect2, varscan2
- PCNT | c.4669G>T p.V1557L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100855518; called by muse, mutect2, varscan2
- PCSK5 | c.4895C>T p.A1632V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.497); catalogued as rs1223721563, COSV101377409, COSV70450027; called by muse, mutect2, varscan2
- PDCL | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV52342197, COSV99414126; called by mutect2, varscan2
- PDE1C | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs750886348, COSV100372607; called by muse, mutect2, varscan2
- PDE3B | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as rs781661071, COSV56391739; called by muse, mutect2, varscan2
- PDE4DIP | c.5600G>A p.R1867H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs375617654; called by muse, mutect2, varscan2
- PDIA5 | c.1157del p.P386Rfs*26 | Frame Shift Del (DEL) | VAF 65/96 reads (68%) | catalogued as rs766425459, COSV60251765; called by mutect2, pindel, varscan2
- PDZD2 | c.308del p.G103Afs*19 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs750970663; called by mutect2, pindel, varscan2
- PDZK1 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV100572444; called by muse, mutect2, varscan2
- PEBP1 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99731950; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs1163689977; called by mutect2, varscan2
- PIBF1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100411522; called by muse, varscan2
- PIK3R1 | c.1924C>T p.R642* (on ENST00000521381 / NM_181523.3; = p.R372* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 31/43 reads (72%) | catalogued as rs1419325070, COSV57123056; called by muse, mutect2, varscan2
- PIK3R4 | c.2809A>T p.I937F | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100768406; called by muse, mutect2, varscan2
- PITPNM1 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99653690; called by muse, mutect2, varscan2
- PIWIL2 | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV100769412; called by muse, mutect2, varscan2
- PKD1 | c.7801C>T p.R2601W | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs376429519; called by muse, mutect2, varscan2
- PLCB2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs752587719, COSV99542103, COSV99542915; called by muse, mutect2, varscan2
- PLEC | c.10285G>A p.V3429M (on ENST00000322810 / NM_201380.4; = p.V3319M on NM_000445.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs782650325, COSV59713325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.2023C>T p.R675C (on ENST00000322810 / NM_201380.4; = p.R565C on NM_000445.5) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs782678779, COSV100514295, COSV59676279; called by muse, mutect2, varscan2
- PLXNC1 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 92/98 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99313150; called by muse, varscan2
- PMPCB | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV99971277; called by muse, mutect2, varscan2
- PNMA8B | c.1429T>A p.Y477N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV100885416; called by muse, mutect2, varscan2
- POLH | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762176747, COSV100947681, COSV100947776; called by muse, mutect2, varscan2
- POLI | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99471083; called by muse, mutect2, varscan2
- POLQ | c.7206G>A p.M2402I | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99952284; called by muse, mutect2, varscan2
- PPP3CA | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547698; called by muse, mutect2, varscan2
- PRG4 | c.3547C>T p.R1183C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs766427843, COSV100798218; called by muse, mutect2, varscan2
- PRRC2B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1212621247, COSV61933496; called by muse, mutect2, varscan2
- PSRC1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV100883514; called by muse, mutect2, varscan2
- PTK6 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748934769, COSV53916454; called by muse, varscan2
- PTK7 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs552297655, COSV100030188; called by muse, varscan2
- PTP4A3 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs867220700, COSV61472494; called by muse, mutect2, varscan2
- PTPN21 | c.3098G>A p.R1033H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752596905, COSV100161880; called by muse, mutect2, varscan2
- PTPRR | c.89dup p.L30Ffs*4 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs1428737881; called by mutect2, pindel, varscan2
- PUF60 | c.965C>G p.A322G (on ENST00000526683 / NM_001362896.2; = p.A305G on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV100253337; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 43/103 reads (42%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- RADX | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV65317787, COSV65319445; called by muse, mutect2, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV99173620; called by mutect2, pindel, varscan2
- RAPGEF4 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99910673; called by muse, mutect2, varscan2
- RARS1 | c.1847A>G p.Y616C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99199097; called by muse, mutect2, varscan2
- RBM14 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV100036745, COSV59560566; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 29/60 reads (48%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | catalogued as rs749563266; called by mutect2, varscan2
- RBM6 | c.293dup p.D99Rfs*6 | Frame Shift Ins (INS) | VAF 14/18 reads (78%) | catalogued as rs764709206; called by mutect2, varscan2
- RELN | c.8306T>A p.I2769N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100633759; called by muse, mutect2, varscan2
- RESF1 | c.2675T>A p.I892N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100440358; called by muse, mutect2, varscan2
- RFLNB | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs868916068, COSV100225063; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHOU | c.321G>A p.Q107= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100797167, COSV64208535; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RORA | c.1070A>C p.K357T (on ENST00000335670 / NM_134261.3; = p.K382T on NM_002943.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99832677; called by muse, mutect2, varscan2
- ROS1 | c.168G>A p.P56= | Splice Region (SNP) | VAF 18/48 reads (38%) | catalogued as rs553213552, COSV100877091; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/36 reads (67%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS24 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100680628; called by muse, mutect2, varscan2
- RPS6KA2 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1242873180, COSV99690899; called by muse, mutect2, varscan2
- RPTN | c.1314C>A p.H438Q | Missense Mutation (SNP) | VAF 66/337 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100285506; called by muse, mutect2, varscan2
- RTN4RL2 | c.512A>T p.Q171L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV100625458; called by muse, mutect2, varscan2
- RYR1 | c.10745G>A p.R3582H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as rs142491855; called by muse, mutect2, varscan2
- RYR2 | c.6374A>G p.Q2125R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs1381877182, COSV100770304; called by muse, mutect2, varscan2
- SAFB | c.2399dup p.Y801Lfs*4 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | catalogued as rs747412640; called by mutect2, varscan2
- SAFB2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.123); catalogued as rs369736320; called by muse, mutect2, varscan2
- SAMD3 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100148248; called by muse, mutect2, varscan2
- SCAP | c.3775G>A p.V1259I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV99650586; called by muse, mutect2, varscan2
- SCN2A | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99331767; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC63 | c.1586del p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs758487924; called by mutect2, varscan2
- SEMA3E | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100318566; called by muse, mutect2, varscan2
- SEMA4C | c.789C>T p.G263= | Splice Region (SNP) | VAF 15/27 reads (56%) | catalogued as rs777990010, COSV59692168; called by muse, mutect2, varscan2
- SESN2 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99455726; called by muse, mutect2, varscan2
- SETD3 | c.196+2T>C p.X66_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100075075; called by muse, mutect2
- SF3B1 | c.3569C>A p.A1190E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV100134751; called by muse, mutect2, varscan2
- SF3B3 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100209890; called by muse, mutect2, varscan2
- SGTB | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101121599; called by muse, mutect2, varscan2
- SHANK2 | c.3674G>A p.R1225Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370031971; called by muse, mutect2, varscan2
- SHOC1 | c.1539dup p.Q514Tfs*4 | Frame Shift Ins (INS) | VAF 17/61 reads (28%) | catalogued as rs1321256439; called by mutect2, pindel, varscan2
- SIM1 | c.2242C>A p.Q748K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.107); catalogued as COSV99492371; called by muse, mutect2, varscan2
- SIPA1L1 | c.2607_2609del p.N869del | In Frame Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs1311386483; called by pindel, varscan2
- SLC18A1 | c.1445del p.P482Rfs*10 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV99368642; called by mutect2, pindel
- SLC26A11 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV63279083; called by muse, mutect2, varscan2
- SLC26A8 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV100839469; called by muse, mutect2, varscan2
- SLC44A2 | c.1351T>G p.F451V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); catalogued as COSV100213211; called by muse, mutect2, varscan2
- SLC6A13 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100569943; called by muse, mutect2, varscan2
- SLFN11 | c.406T>G p.S136A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.914); catalogued as COSV100390642; called by muse, mutect2, varscan2
- SLITRK5 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280771; called by muse, mutect2, varscan2
- SMAGP | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV101199397; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 26/44 reads (59%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCA1 | c.2977C>T p.R993* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100946546; called by muse, mutect2, varscan2
- SNX10 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100640102; called by muse, mutect2, varscan2
- SOAT2 | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100037485; called by muse, mutect2, varscan2
- SORBS2 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV99511007; called by muse, mutect2, varscan2
- SPAG9 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.149); catalogued as rs772202821, COSV100005207; called by muse, mutect2, varscan2
- SPARCL1 | c.399dup p.L134Tfs*6 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | catalogued as rs1430929583; called by mutect2, pindel, varscan2
- SPRR2B | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.693); catalogued as rs761935856, COSV100482294; called by muse, varscan2
- SPTLC3 | c.271T>C p.C91R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs757704377, COSV100983133; called by muse, mutect2, varscan2
- SSH3 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs765623534, COSV100354573; called by muse, mutect2, varscan2
- SSTR4 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as rs749577596, COSV54799500; called by muse, varscan2
- ST8SIA1 | c.67T>C p.F23L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99683175; called by muse, mutect2
- STK33 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV100174056; called by muse, varscan2
- STMN3 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100899864; called by muse, mutect2, varscan2
- STON2 | c.2329dup p.L777Pfs*7 (on ENST00000649389 / NM_001366849.2; = p.L720Pfs*7 on NM_001256430.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as rs760038848; called by mutect2, pindel, varscan2
- SUCNR1 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62913045; called by muse, mutect2, varscan2
- SUMF2 | c.186T>A p.N62K (on ENST00000652303; = p.N43K on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.085); catalogued as rs1472152555, COSV99303466; called by muse, mutect2, varscan2
- SUV39H2 | c.602G>A p.C201Y (on ENST00000354919 / NM_001193424.2; = p.C141Y on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543104; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as rs570102997; called by mutect2, varscan2
- SYDE1 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100720652; called by muse, varscan2
- TAF1L | c.1852T>C p.W618R | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54257347; called by muse, mutect2, varscan2
- TAP1 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs778774698, COSV62754343; called by muse, mutect2, varscan2
- TARBP2 | c.680C>T p.T227M (on ENST00000266987 / NM_134323.2; = p.T206M on NM_004178.4) | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs765847634, COSV99908502; called by muse, mutect2, varscan2
- TASOR | c.2086G>A p.G696S (on ENST00000355628 / NM_001365636.2; = p.G300S on NM_015224.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV62926859; called by muse, mutect2
- TBXAS1 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695365, COSV99695690; called by muse, mutect2, varscan2
- TECPR1 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs531633517, COSV101130505; called by muse, mutect2, varscan2
- TEKT5 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200608852, COSV99296104; called by muse, mutect2, varscan2
- TENM1 | c.2032G>T p.V678L | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100950066; called by muse, mutect2, varscan2
- THSD4 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1022028200, COSV99965596; called by muse, mutect2, varscan2
- TMEM45B | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as rs765825131, COSV99859269; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS11A | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100602684; called by muse, mutect2, varscan2
- TMX3 | c.710T>C p.F237S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100218347; called by muse, mutect2, varscan2
- TNKS1BP1 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100836040; called by muse, mutect2, varscan2
- TNNI1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1023922407, COSV100270299; called by muse, mutect2, varscan2
- TNPO1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs1008592158, COSV61521795; called by muse, mutect2, varscan2
- TRAV13-2 | c.283_284dup p.Q96Cfs*? | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | catalogued as rs751832473; called by mutect2, varscan2
- TRDMT1 | c.279T>A p.D93E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100003943; called by muse, mutect2, varscan2
- TRIM55 | c.860del p.I288Sfs*13 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1354534266; called by mutect2, pindel, varscan2
- TRIM72 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs768721119, COSV100265421; called by muse, mutect2, varscan2
- TRIO | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs761019734, COSV60094907; called by muse, mutect2, varscan2
- TRPV3 | c.259del p.Q87Sfs*7 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | catalogued as rs911130511, COSV100027514; called by mutect2, pindel, varscan2
- TSNAX | c.223C>G p.H75D | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100791107; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 30/38 reads (79%) | catalogued as rs763254614; called by mutect2, varscan2
- TXNRD1 | c.481T>C p.Y161H (on ENST00000525566 / NM_001093771.3; = p.Y63H on NM_003330.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV100723458; called by muse, mutect2, varscan2
- TYK2 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs371919786; called by muse, mutect2, varscan2
- TYW5 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100662438; called by muse, mutect2, varscan2
- UBE2J1 | c.106-1G>T p.X36_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV101470244; called by muse, mutect2, varscan2
- UBR1 | c.5140C>T p.R1714W | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777158316, COSV99317253; called by muse, mutect2, varscan2
- UBR5 | c.6314C>T p.A2105V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99640906; called by muse, mutect2, varscan2
- UCHL5 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100815389; called by muse, mutect2, varscan2
- UGT2B15 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100592322; called by muse, mutect2
- UNC5A | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs761967527, COSV99458558; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs767420916; called by mutect2, varscan2
- USP10 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV99551417; called by muse, mutect2, varscan2
- USP18 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99306098; called by muse, mutect2, varscan2
- USP25 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.601); catalogued as COSV99583805; called by muse, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- UTP6 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99911951; called by muse, mutect2, varscan2
- VOPP1 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as COSV53390629; called by mutect2, pindel, varscan2
- VPS13A | c.9102G>T p.E3034D | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.174); catalogued as COSV100652832, COSV62431868; called by muse, mutect2, varscan2
- VPS50 | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52498143; called by muse, mutect2, varscan2
- WDR18 | c.26T>A p.V9E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99242846; called by muse, varscan2
- YY1AP1 | c.1540C>T p.P514S (on ENST00000295566 / NM_139118.2; = p.P457S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.954); catalogued as COSV99804110; called by muse, mutect2, varscan2
- Z83844.2 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as rs772506359, COSV99312851; called by muse, mutect2, varscan2
- ZC3H11A | c.35del p.F12Sfs*20 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs768425662; called by mutect2, varscan2
- ZFR | c.1074dup p.E359Rfs*27 | Frame Shift Ins (INS) | VAF 68/166 reads (41%) | catalogued as rs751974853; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF208 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as rs751321356, COSV101237026; called by muse, mutect2, varscan2
- ZNF561 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.228); catalogued as rs754290323, COSV100254523; called by muse, mutect2
- ZNF674 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101345041; called by muse, mutect2, varscan2
- ZNF714 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV52510918, COSV99395263; called by muse, mutect2, varscan2
- ZSWIM8 | c.4310G>A p.G1437E (on ENST00000605216 / NM_001242487.2; = p.G1442E on NM_015037.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.469); catalogued as COSV100014002; called by muse, mutect2
- ACACA | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ADORA2B | c.342_343del p.S115Ffs*32 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- AOC3 | c.1318del p.L440Cfs*46 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- AVPR2 | c.631del p.L211* | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.4222del p.R1408Afs*21 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- BAIAP2L2 | c.1167del p.V390* | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- CCSER2 | c.652del p.M218Wfs*2 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- CEP350 | c.8326del p.T2776Pfs*21 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- CR2 | c.2919dup p.A974Cfs*54 | Frame Shift Ins (INS) | VAF 14/149 reads (9%) | called by mutect2, pindel
- CRIM1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.219); called by muse, mutect2
- CTTNBP2 | c.322del p.L108Sfs*65 | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- CYTH3 | c.1111_1113del p.E371del (on ENST00000396741; = p.E370del on NM_004227.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 16/34 reads (47%) | called by pindel, varscan2
- DAAM2 | c.1574dup p.G526Wfs*14 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- DOCK3 | c.5554_5555del p.P1852Sfs*46 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by pindel, varscan2*
- DPP8 | c.2272_2281del p.G758Pfs*2 (on ENST00000341861 / NM_001320875.2; = p.G742Pfs*2 on NM_130434.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- DST | c.5686del p.I1896* | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- E2F2 | c.1069dup p.Q357Pfs*16 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- EGFL7 | c.549del p.R184Gfs*13 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- EGR3 | c.490del p.Q164Rfs*27 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- EMC2 | c.752del p.K251Rfs*4 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- FBXL7 | c.278del p.P93Rfs*22 | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | called by mutect2, pindel, varscan2
- FILIP1 | c.91del p.S31Vfs*29 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- GGH | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GNB3 | c.728del p.T243Rfs*19 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- GON4L | c.400del p.M134* | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | called by mutect2, pindel, varscan2
- HIGD1B | c.256_258del p.S86del | In Frame Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- HR | c.148del p.W50Gfs*5 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by mutect2, pindel, varscan2
- IFNL1 | c.352del p.L118Ffs*74 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- INPP5D | c.1253del p.P418Lfs*31 (on ENST00000445964 / NM_001017915.3; = p.P417Lfs*31 on NM_005541.5) | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- IRS4 | c.2691dup p.G898Rfs*3 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- ITGB8 | c.1337dup p.N446Kfs*11 | Frame Shift Ins (INS) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 24/42 reads (57%) | called by mutect2, varscan2
- KMT2D | c.11920_11922dup p.Q3974dup | In Frame Ins (INS) | VAF 41/49 reads (84%) | called by mutect2, varscan2
- KMT2D | c.5879del p.G1960Afs*87 | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- KRIT1 | c.143dup p.R49Efs*15 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- KRT40 | c.714_715del p.G239Rfs*14 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- LMTK2 | c.548dup p.L183Ffs*33 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- LRP1B | c.5606del p.K1869Rfs*9 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- M6PR | c.576_579del p.L193Sfs*21 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- MAP1A | c.7434del p.R2479Gfs*4 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- MCM4 | c.1885del p.T629Qfs*18 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, varscan2
- MYOM1 | c.4375del p.I1459* | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- NCOA2 | c.1758del p.F586Lfs*36 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | called by mutect2, pindel, varscan2
- NFAM1 | c.745dup p.L249Pfs*8 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- NPY1R | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- OR2T6 | c.483del p.I162Lfs*3 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- OR2V2 | c.177del p.M60Cfs*78 | Frame Shift Del (DEL) | VAF 105/198 reads (53%) | called by mutect2, pindel, varscan2
- OR5B17 | c.527del p.F176Sfs*10 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- OTOF | c.1681del p.E561Rfs*18 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- OVOL2 | c.509_510dup p.G171Qfs*25 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- PARD6A | c.473_490del p.V158_H163del | In Frame Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- PKNOX1 | c.475_476del p.L159Vfs*76 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by pindel, varscan2
- PKP4 | c.1743_1744del p.H581Qfs*24 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | called by pindel, varscan2
- PLXNB1 | c.909del p.T304Lfs*102 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- PNKP | c.431del p.N144Tfs*11 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- PNLDC1 | c.30del p.F10Lfs*9 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- PTEN | c.335_348del p.L112Qfs*9 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | called by pindel, varscan2
- RBM25 | c.1996del p.I666* | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | called by mutect2, pindel, varscan2
- RNF165 | c.128del p.P43Rfs*40 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- SIGLEC1 | c.954del p.I319Sfs*12 | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | called by mutect2, pindel, varscan2
- SNRPA | c.396del p.V133Wfs*15 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- SOX9 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPTY2D1 | c.96del p.D33Tfs*23 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by pindel, varscan2
- SSH2 | c.3220del p.Q1074Kfs*24 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- ST18 | c.768_772del p.K257Pfs*19 | Frame Shift Del (DEL) | VAF 25/43 reads (58%) | called by pindel, varscan2
- STAC2 | c.304dup p.L102Pfs*21 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- STX16 | c.593del p.F198Sfs*7 (on ENST00000371141 / NM_001001433.3; = p.F177Sfs*7 on NM_003763.6) | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- SV2C | c.291del p.S98Vfs*2 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- SYNE2 | c.3074del p.K1025Rfs*2 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- TAF1C | c.2120del p.P707Lfs*7 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- TASOR | c.4140_4142del p.K1380del (on ENST00000355628 / NM_001365636.2; = p.K1004del on NM_015224.3) | In Frame Del (DEL) | VAF 4/35 reads (11%) | called by pindel, varscan2
- TFAM | c.291dup p.I98Nfs*7 | Frame Shift Ins (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- TLL1 | c.1716del p.F572Lfs*20 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- TRGC1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSFM | c.369_370del p.C123* | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by pindel, varscan2
- TSPAN10 | c.810del p.V272Cfs*144 (on ENST00000574882 / NM_001290212.1; = p.V234Cfs*? on NM_031945.4) | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- UBR5 | c.116del p.P39Lfs*2 | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | called by mutect2, pindel, varscan2
- USP13 | c.353del p.L118* | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- UTP15 | c.1346_1347dup p.L450Ifs*4 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | called by mutect2, varscan2
- UTRN | c.4457_4460del p.S1486Kfs*9 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- VPS50 | c.1771del p.S591Afs*9 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- ZDHHC6 | c.675del p.F225Lfs*4 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- ZEB2 | c.3595del p.M1199Wfs*42 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- ZKSCAN5 | c.1623del p.K541Nfs*52 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- ZNF236 | c.2932_2934del p.K978del | In Frame Del (DEL) | VAF 18/45 reads (40%) | called by pindel, varscan2
- ABCB6 | c.591A>G p.G197= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV99521874; called by muse, mutect2, varscan2
- AC005324.2 | c.1162C>T p.L388= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100371878; called by muse, mutect2, varscan2
- ACBD6 | c.378T>C p.N126= | Silent (SNP) | VAF 4/81 reads (5%) | called by muse, mutect2
- ADAMTS10 | c.3238C>T p.L1080= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99546946; called by muse, mutect2, varscan2
- ADAMTS18 | c.222A>G p.S74= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs764755435, COSV99272699; called by muse, mutect2, varscan2
- ADPRHL1 | c.987G>A p.L329= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs746139532, COSV100733427; called by muse, mutect2, varscan2
- ADRA1B | c.12C>T p.D4= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60702308; called by muse, mutect2, varscan2
- AKAP9 | c.6573G>A p.A2191= (on ENST00000359028; = p.A2159= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs780419888, COSV100662416; called by muse, mutect2, varscan2
- AMDHD2 | c.948C>T p.D316= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs542092616, COSV53552169; called by muse, mutect2, varscan2
- APBA1 | c.2046C>T p.T682= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs981233867, COSV99596105; called by muse, mutect2, varscan2
- ASPM | c.4971A>G p.T1657= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs369031263; called by muse, mutect2, varscan2
- B3GNT3 | c.702C>T p.F234= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs371110502; called by muse, mutect2, varscan2
- CCHCR1 | c.1651C>T p.L551= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99458875; called by muse, mutect2, varscan2
- CCKBR | c.1263C>T p.P421= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1455464208, COSV58105245; called by muse, mutect2, varscan2
- CCNT1 | c.1647C>T p.S549= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99980753; called by muse, mutect2, varscan2
- COL22A1 | c.3021C>T p.C1007= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs376513266; called by muse, mutect2, varscan2
- COQ3 | c.276C>T p.V92= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs751957396, COSV54640212; called by muse, mutect2, varscan2
- CPXCR1 | c.795T>A p.V265= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99342221; called by muse, mutect2, varscan2
- CSMD2 | c.7665C>T p.Y2555= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs957389992, COSV99590156; called by muse, mutect2, varscan2
- CYP2S1 | c.1332C>T p.G444= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- CYP4X1 | c.1368G>A p.G456= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs925845443, COSV100903308; called by muse, mutect2, varscan2
- DCC | c.117A>G p.A39= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100500171; called by muse, mutect2, varscan2
- DNAH17 | c.11760C>T p.N3920= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs777605812, COSV67749190; called by muse, mutect2, varscan2
- DNAH5 | c.3468T>C p.I1156= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV99449947; called by muse, mutect2, varscan2
- DNAJC1 | c.963A>G p.R321= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs1387404095, COSV100981316; called by muse, mutect2, varscan2
- DOP1A | c.5049A>G p.T1683= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99381951; called by muse, mutect2, varscan2
- EGFLAM | c.2685C>T p.G895= (on ENST00000354891 / NM_001205301.2; = p.G887= on NM_152403.4) | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV100380303; called by muse, mutect2, varscan2
- EIF2AK4 | c.2244C>T p.S748= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- EMSY | c.1908G>A p.T636= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs767597942, COSV100595234, COSV58263225; called by muse, mutect2, varscan2
- ENAH | c.1650G>A p.T550= (on ENST00000366844 / NM_001008493.3; = p.T529= on NM_018212.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs368744442, COSV99490165; called by muse, mutect2, varscan2
- FERMT3 | c.42G>A p.S14= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs1179556498, COSV99656595; called by muse, mutect2, varscan2
- FGF4 | c.390C>T p.G130= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99395365; called by muse, mutect2, varscan2
- FLG | c.6624G>A p.S2208= | Silent (SNP) | VAF 54/261 reads (21%) | catalogued as rs144679024; called by muse, mutect2, varscan2
- FRMPD1 | c.423G>A p.S141= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs765980830, COSV100899562; called by muse, mutect2, varscan2
- GFM2 | c.1383C>T p.A461= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as rs770823586, COSV99714349; called by muse, mutect2, varscan2
- GJB6 | c.633C>T p.C211= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV53832203; called by muse, mutect2
- GLI2 | c.4173C>T p.S1391= (on ENST00000361492 / NM_001374353.1; = p.S1408= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100083232; called by muse, mutect2, varscan2
- GREM1 | c.462C>A p.V154= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100277955; called by muse, mutect2, varscan2
- GTSE1 | c.1281C>T p.G427= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1191198259, COSV101483216, COSV71889636; called by muse, mutect2, varscan2
- HOXD1 | c.462C>T p.Y154= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100514176; called by muse, mutect2, varscan2
- INCENP | c.1362G>A p.K454= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99611050; called by muse, mutect2, varscan2
- INSM2 | c.42C>T p.G14= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1026451359, COSV99354832; called by muse, mutect2, varscan2
- IPO13 | c.610C>T p.L204= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs371543125; called by muse, mutect2, varscan2
- IRAG2 | c.4284G>A p.Q1428= (on ENST00000636465; = p.Q473= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100209344; called by muse, mutect2, varscan2
- IZUMO2 | c.204C>T p.Y68= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99518268; called by muse, mutect2, varscan2
- JMJD7 | c.732G>A p.A244= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs376080091, COSV100583837; called by muse, varscan2
- KCNH8 | c.612T>G p.V204= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV100109876; called by muse, mutect2
- LAMA1 | c.8802T>C p.T2934= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV101056438; called by muse, mutect2, varscan2
- LAMA1 | c.6094C>T p.L2032= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV67535882; called by muse, mutect2, varscan2
- LPIN1 | c.966G>A p.S322= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs368925424; called by muse, mutect2
- LPIN3 | c.1818G>A p.L606= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs772220229, COSV100182571, COSV60039231; called by muse, mutect2, varscan2
- LRGUK | c.1311G>A p.Q437= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99604231; called by muse, mutect2
- MCM10 | c.1392T>A p.V464= (on ENST00000484800 / NM_182751.3; = p.V463= on NM_018518.5) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101098145; called by muse, mutect2, varscan2
- MCTP2 | c.681G>A p.T227= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1418936905, COSV59149271; called by muse, mutect2, varscan2
- MED13L | c.3192C>T p.G1064= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99928879; called by muse, mutect2, varscan2
- MEF2C | c.1248G>A p.A416= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as COSV60935300; called by muse, mutect2, varscan2
- MEST | c.834T>C p.F278= | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as COSV99784255; called by muse, mutect2, varscan2
- MTRR | c.198T>C p.S66= (on ENST00000264668; = p.S39= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99241726; called by muse, mutect2, varscan2
- MTUS1 | c.2259T>A p.P753= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100029446; called by muse, mutect2, varscan2
- MUC5AC | c.14928G>A p.P4976= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs377577320, COSV100611458; called by muse, mutect2, varscan2
- MYH11 | c.4713G>A p.A1571= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs141198584; called by muse, mutect2, varscan2
- MYO1C | c.240T>C p.I80= (on ENST00000648651 / NM_001080779.2; = p.I45= on NM_033375.5) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100704369; called by muse, mutect2, varscan2
- MYOM2 | c.2964C>T p.D988= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs139273975, COSV50701992; called by muse, mutect2, varscan2
- NDUFB9 | c.432G>A p.T144= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs773497765, COSV99412805; called by muse, mutect2, varscan2
- NEGR1 | c.996C>T p.C332= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV60867316; called by muse, mutect2, varscan2
- NFATC1 | c.729C>T p.R243= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs768838244, COSV99501670; called by muse, varscan2
- NKAPD1 | c.759G>A p.K253= (on ENST00000280352 / NM_001082970.2; = p.K254= on NM_018195.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99735953; called by muse, mutect2, varscan2
- NPEPPS | c.2178T>A p.R726= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100443704; called by muse, mutect2, varscan2
- NSD2 | c.2247G>A p.L749= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100373321; called by muse, mutect2, varscan2
- NUP155 | c.1140A>G p.A380= (on ENST00000231498 / NM_153485.3; = p.A321= on NM_004298.4) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1432220549, COSV99192894; called by muse, mutect2, varscan2
- NUP98 | c.2124G>A p.T708= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs201614203, COSV100262427; called by muse, mutect2, varscan2
- NUTM2G | c.636C>G p.L212= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs1461666052, COSV100672857; called by muse, mutect2, varscan2
- OBSCN | c.16167C>A p.T5389= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52821814; called by muse, varscan2
- ONECUT1 | c.336G>A p.L112= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100009241; called by muse, mutect2, varscan2
- PCDHA12 | c.1446G>A p.A482= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as COSV100250542; called by muse, mutect2, varscan2
- PHF19 | c.1491C>T p.R497= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100876352; called by muse, mutect2, varscan2
- PHF3 | c.5358C>T p.S1786= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs561879635, COSV100013377; called by muse, mutect2, varscan2
- PIK3C2B | c.2103G>A p.R701= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100916128; called by muse, mutect2, varscan2
- PITPNM2 | c.2185C>T p.L729= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as rs749710959, COSV99758989; called by muse, mutect2, varscan2
- PLA2G3 | c.1194G>A p.T398= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs201442680, COSV53210629; called by muse, mutect2, varscan2
- PNCK | c.567C>T p.Y189= (on ENST00000340888 / NM_001366975.1; = p.Y272= on NM_001039582.3) | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs377279617, COSV100562314; called by muse, mutect2, varscan2
- PPP3R2 | c.327C>T p.N109= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV62450353; called by muse, mutect2, varscan2
- PRELID3B | c.561A>G p.A187= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs757738795, COSV54812428; called by muse, mutect2, varscan2
- PRKD2 | c.1374G>A p.V458= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1379742945, COSV99354318; called by muse, mutect2, varscan2
- PRPF40B | c.1506C>T p.D502= (on ENST00000380281; = p.D496= on NM_012272.3) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs752835790, COSV99979841; called by muse, mutect2, varscan2
- PTMA | c.198G>A p.E66= (on ENST00000341369 / NM_001099285.2; = p.E65= on NM_002823.5) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1182529369, COSV100398386; called by muse, mutect2, varscan2
- PYGL | c.2004C>T p.S668= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1215406679, COSV53585011; called by muse, mutect2, varscan2
- PYROXD2 | c.1111C>A p.R371= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100995983, COSV65328748; called by muse, mutect2, varscan2
- R3HDM2 | c.1347C>T p.R449= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100715194; called by muse, mutect2, varscan2
- RAB22A | c.444C>T p.S148= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs138266092; called by muse, mutect2, varscan2
- RAD23B | c.90T>A p.I30= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100787709; called by muse, mutect2, varscan2
- RELL1 | c.354G>A p.G118= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100025466; called by muse, mutect2, varscan2
- RELN | c.765C>T p.G255= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100633775; called by muse, mutect2
- RHPN2 | c.642G>A p.L214= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99577625; called by muse, mutect2, varscan2
- RNF146 | c.348G>A p.Q116= (on ENST00000368314 / NM_001242850.2; = p.Q115= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100541749; called by muse, mutect2
- ROBO1 | c.4677C>T p.D1559= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs775078217, COSV71398583; called by muse, mutect2, varscan2
- RSRC2 | c.540C>T p.S180= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV59204516; called by muse, mutect2
- SAP130 | c.2757C>T p.D919= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs765629491, COSV52095093; called by muse, mutect2, varscan2
- SCUBE3 | c.339G>T p.V113= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99234494; called by muse, mutect2, varscan2
- SEC16B | c.900C>T p.D300= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs761699854, COSV100381598; called by muse, mutect2, varscan2
- SESN2 | c.771C>T p.D257= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs960381759, COSV99455721; called by muse, mutect2, varscan2
- SETD1A | c.3159G>A p.S1053= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs754761831, COSV99353023; called by muse, mutect2, varscan2
- SGCA | c.1053C>T p.R351= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs148373921; called by muse, mutect2, varscan2
- SLC20A2 | c.666C>T p.V222= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs772314521, COSV100646075; called by muse, mutect2, varscan2
- SLC22A9 | c.285G>A p.Q95= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99655026; called by muse, mutect2, varscan2
- SLITRK3 | c.1836A>C p.P612= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99579276; called by muse, mutect2, varscan2
- SMARCA5 | c.1677G>C p.T559= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs61761959; called by muse, mutect2
- SMOC2 | c.1257C>T p.D419= (on ENST00000356284 / NM_001166412.2; = p.D430= on NM_022138.3) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs151010390, COSV62438807; called by muse, mutect2, varscan2
- SNTA1 | c.1497C>A p.T499= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs771855211, COSV99458714; called by muse, mutect2, varscan2
- SNX13 | c.2475T>C p.T825= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101296835; called by muse, mutect2, varscan2
- SOX7 | c.282C>T p.Y94= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs774710894, COSV58730576; called by muse, mutect2, varscan2
- SPPL2A | c.1332T>C p.Y444= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99961603; called by muse, mutect2, varscan2
- SRD5A2 | c.255C>T p.G85= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs904274646, COSV99252390; called by muse, mutect2, varscan2
- ST14 | c.1176G>A p.V392= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99598756; called by mutect2, varscan2
- STOX2 | c.237C>T p.C79= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100408721; called by muse, mutect2, varscan2
- SUSD4 | c.1362C>T p.H454= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs999424595, COSV100663762; called by muse, mutect2, varscan2
- SYNPO | c.2742C>T p.N914= (on ENST00000394243 / NM_001166208.2; = p.N670= on NM_007286.6) | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs139882602; called by muse, mutect2, varscan2
- SYT3 | c.1587C>T p.N529= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1366824485, COSV100144101; called by muse, mutect2, varscan2
- TCTE1 | c.1156T>C p.L386= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV101025436; called by muse, mutect2
- TGFB1I1 | c.1311G>A p.P437= (on ENST00000394863 / NM_001042454.3; = p.P420= on NM_015927.4) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100691068; called by muse, mutect2, varscan2
- TGM1 | c.396C>T p.D132= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs376590179; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMC2 | c.627C>T p.Y209= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100727614; called by muse, mutect2, varscan2
- TNFRSF8 | c.1453C>T p.L485= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1293905475, COSV99821464; called by muse, mutect2, varscan2
- TNRC18 | c.4681C>T p.L1561= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs1172325797, COSV101269670; called by muse, mutect2, varscan2
- TRIB3 | c.660C>T p.H220= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs374329385; called by muse, mutect2, varscan2
- TRIM7 | c.1380C>T p.R460= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1162112812, COSV99220219; called by muse, mutect2
- TRIP12 | c.525T>C p.P175= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV99390288; called by muse, mutect2, varscan2
- TRPV1 | c.2274C>T p.G758= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99439642; called by muse, mutect2, varscan2
- TSHZ1 | c.2320C>T p.L774= (on ENST00000580243 / NM_001308210.2; = p.L729= on NM_005786.6) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100433702; called by muse, mutect2, varscan2
- TSHZ2 | c.90G>A p.E30= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV61588654; called by muse, mutect2, varscan2
- TTI1 | c.78A>G p.T26= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100989640; called by muse, mutect2, varscan2
- TXNDC11 | c.1452G>A p.S484= (on ENST00000356957 / NM_001303447.2; = p.S457= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs534475681, COSV99297755; called by muse, mutect2, varscan2
- VARS2 | c.1023G>A p.T341= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs572473514, COSV99461850; called by muse, varscan2
- VWA5A | c.600C>A p.P200= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100795657, COSV63707620; called by muse, mutect2, varscan2
- WIPF1 | c.231C>T p.G77= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs772302114, COSV55821139; ClinVar: uncertain significance; called by muse, varscan2
- WNT5B | c.51T>C p.A17= | Silent (SNP) | VAF 31/33 reads (94%) | catalogued as COSV100148687; called by muse, mutect2, varscan2
- ZGPAT | c.405C>T p.S135= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100157601; called by muse, mutect2, varscan2
- ZNF18 | c.648G>A p.L216= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100503109; called by muse, mutect2, varscan2
- ZNF263 | c.1677C>A p.T559= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99526925; called by muse, mutect2, varscan2
- ZNF333 | c.66C>T p.S22= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as rs769798251, COSV52885041; called by muse, mutect2, varscan2
- ZNF446 | c.13C>T p.L5= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52181389; called by muse, mutect2
- ZNF470 | c.879C>T p.F293= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1325446796, COSV100401231, COSV57968241; called by muse, mutect2, varscan2
- ZXDC | c.1149C>T p.D383= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs755866318, COSV100306464; called by muse, mutect2, varscan2
- ADD2 | c.1742-300C>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as rs781870620, COSV100034982; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097106 G>A | 3'Flank (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823055 del T | 5'Flank (DEL) | VAF 30/43 reads (70%) | catalogued as rs755255238; called by mutect2, varscan2
- AL353804.4 | chrX:73825442 ins T | 5'Flank (INS) | VAF 6/7 reads (86%) | called by mutect2, varscan2
- AP000769.5 | chr11:65500852 T>A | 5'Flank (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- BRSK2 | c.1939+277del | Intron (DEL) | VAF 6/20 reads (30%) | catalogued as rs751872197, COSV100373197; called by mutect2, varscan2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 14/60 reads (23%) | catalogued as rs754124024; called by mutect2, pindel, varscan2
- CETN1 | c.*1A>G | 3'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100511327; called by muse, mutect2, varscan2
- DCHS2 | n.1909G>A | RNA (SNP) | VAF 6/19 reads (32%) | catalogued as rs748825622, COSV100251790; called by muse, mutect2, varscan2
- DNM1L | c.*1529C>T | 3'UTR (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99846091; called by muse, mutect2, varscan2
- IGF2 | c.-4+213T>C | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as rs756188479, COSV100324057; called by muse, varscan2
- KIF16B | c.3498+3119C>T | Intron (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100734312; called by muse, mutect2, varscan2
- LIM2 | c.175+28G>A | Intron (SNP) | VAF 19/32 reads (59%) | catalogued as rs199913969, COSV55741027, COSV99702300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LONP2 | chr16:48361765 C>T | 3'Flank (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53520797; called by muse, mutect2, varscan2
- MDS2 | chr1:23627160 C>T | 5'Flank (SNP) | VAF 23/58 reads (40%) | catalogued as rs746868080; called by muse, mutect2, varscan2
- NSD2 | c.3373-135T>C | Intron (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100373322; called by muse, mutect2, varscan2
- PITPNM2 | c.2404+731G>A | Intron (SNP) | VAF 22/43 reads (51%) | catalogued as rs750913437, COSV99758986; called by muse, mutect2, varscan2
- PRKACB | c.47-91del | Intron (DEL) | VAF 11/45 reads (24%) | catalogued as rs1362035564; called by mutect2, pindel, varscan2
- RIMS2 | c.4064-21242del | Intron (DEL) | VAF 27/56 reads (48%) | called by mutect2, pindel, varscan2
- SFTA3 | n.879A>G | RNA (SNP) | VAF 24/67 reads (36%) | catalogued as COSV101410189; called by muse, mutect2, varscan2
- SSPOP | n.3730del | RNA (DEL) | VAF 12/63 reads (19%) | catalogued as rs754581521; called by mutect2, pindel, varscan2
- VAMP7 | c.*9_*11del | 3'UTR (DEL) | VAF 18/131 reads (14%) | catalogued as rs745860800; called by pindel, varscan2
